Somatic mutation profile of tumor specimen TCGA-N5-A4RJ-01A (aliquot TCGA-N5-A4RJ-01A-11D-A28R-08) from TCGA case TCGA-N5-A4RJ, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Age at diagnosis: 61.2 years (22,341 days).
Specimen TCGA-N5-A4RJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7433af4-2fd5-4a8e-84af-a1c86a73f4c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N5-A4RJ-10A (Blood Derived Normal), aliquot TCGA-N5-A4RJ-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9ec2c71-7460-4033-bb44-b58a5e1d1763

The open-access MAF lists 55 somatic variants for this specimen: 47 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 42, Silent 8, Nonsense Mutation 3, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.1805G>A p.R602Q | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs61749410, CM014292; ClinVar: uncertain significance / not provided / likely pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.2524G>A p.V842I | Missense Mutation (SNP) | VAF 43/103 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1057519738, COSV104371920, COSV54062791; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1099C>T p.R367* (on ENST00000281708 / NM_001349798.2; = p.R287* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 19/54 reads (35%) | hotspot (GDC flag); catalogued as COSV55891887; called by muse, mutect2, varscan2
- NIPBL | c.6892C>T p.R2298C | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80358376, CM042519, CM062919, COSV56950513; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3139C>T p.H1047Y | Missense Mutation (SNP) | VAF 41/83 reads (49%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen benign (0); catalogued as rs121913281, CM126699, COSV55876499, COSV55912376; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 38/45 reads (84%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ALDH3A1 | c.1033G>A p.V345M | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as rs746369217; called by mutect2, varscan2
- CCL1 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs780220490, COSV56774449; called by muse, mutect2, varscan2
- CD80 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.134); catalogued as rs267599556; called by muse, mutect2, varscan2
- DHX58 | c.1941C>G p.I647M | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs782471953; called by muse, mutect2, varscan2
- IP6K1 | c.1314C>G p.D438E | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57696592; called by muse, mutect2, varscan2
- KIAA0319 | c.2267G>T p.R756L | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749156433, COSV65497069; called by muse, mutect2, varscan2
- LMO3 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 31/46 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs751584255, COSV53781759; called by muse, mutect2, varscan2
- LZTS1 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 38/52 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as rs199603808, COSV56115708; called by muse, mutect2, varscan2
- MAGEE2 | c.600G>T p.W200C | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV64897867; called by muse, mutect2, varscan2
- MED4 | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1355953749; called by muse, mutect2, varscan2
- MERTK | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54932706; called by muse, mutect2, varscan2
- MMEL1 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs376308719; called by muse, mutect2, varscan2
- RASL10B | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1555596992; called by muse, mutect2, varscan2
- RNF213 | c.12731C>T p.S4244L | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as rs763130760; called by muse, mutect2, varscan2
- SFMBT2 | c.2243C>T p.S748L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.185); catalogued as rs767676222; called by muse, mutect2
- SMARCA4 | c.4822C>T p.R1608W | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.82); catalogued as rs1568565786, COSV60800284; ClinVar: uncertain significance; called by muse, mutect2
- SYMPK | c.2297C>T p.P766L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as rs777424373, COSV55610651; called by muse, mutect2, varscan2
- SYNE1 | c.20645C>T p.S6882L (on ENST00000367255 / NM_182961.4; = p.S6811L on NM_033071.3) | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as rs373012438; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAF1 | c.2204A>G p.H735R (on ENST00000373790 / NM_138923.4; = p.H756R on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/86 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52107358; called by muse, mutect2, varscan2
- TBC1D8 | c.1877A>G p.N626S | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as rs1356078671; called by muse, mutect2, varscan2
- VPS53 | c.514G>A p.G172R (on ENST00000571805 / NM_001366253.2; = p.G143R on NM_018289.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as rs770563727, COSV52135062; called by muse, mutect2, varscan2
- CALN1 | c.32T>C p.L11S (on ENST00000329008 / NM_001017440.3; = p.L53S on NM_031468.4) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- CUL9 | c.1563_1564del p.W522Efs*5 | Frame Shift Del (DEL) | VAF 57/132 reads (43%) | called by mutect2, pindel, varscan2
- DHRS7C | c.688G>A p.V230M (on ENST00000330255 / NM_001220493.2; = p.V229M on NM_001105571.3) | Missense Mutation (SNP) | VAF 33/40 reads (83%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EXO1 | c.2065G>C p.A689P | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- FAM169A | c.26A>G p.E9G | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- GRM7 | c.670C>A p.L224I | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GTF3A | c.916A>T p.K306* | Nonsense Mutation (SNP) | VAF 29/52 reads (56%) | called by muse, mutect2, varscan2
- HSPA6 | c.1425G>C p.Q475H | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- KBTBD7 | c.286T>G p.F96V | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAML1 | c.1750G>A p.V584I | Missense Mutation (SNP) | VAF 69/226 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- MAP3K4 | c.4258G>T p.E1420* | Nonsense Mutation (SNP) | VAF 37/73 reads (51%) | called by muse, mutect2, varscan2
- MAZ | c.1425A>T p.Q475H | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- MS4A15 | c.596A>T p.H199L (on ENST00000405633 / NM_001098835.2; = p.H106L on NM_152717.3) | Missense Mutation (SNP) | VAF 60/65 reads (92%) | SIFT tolerated (0.47); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MSRB3 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- MZF1 | c.1268G>T p.R423L | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- NME9 | c.160A>T p.I54F (on ENST00000333911 / NM_001349024.2; = p.I32F on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- POU2F1 | c.1642A>C p.T548P (on ENST00000541643 / NM_001365848.1; = p.T571P on NM_002697.4) | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- PRKCQ | c.1445C>T p.T482M | Missense Mutation (SNP) | VAF 189/425 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- SAP130 | c.1095+2T>G p.X365_splice | Splice Site (SNP) | VAF 13/65 reads (20%) | called by muse, mutect2, varscan2
- SNRPA | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CD248 | c.1686T>C p.G562= | Silent (SNP) | VAF 52/108 reads (48%) | called by muse, mutect2, varscan2
- CDR1 | c.747C>T p.T249= | Silent (SNP) | VAF 104/117 reads (89%) | called by muse, mutect2, varscan2
- DGKB | c.504C>T p.F168= | Silent (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- GAB4 | c.162G>A p.K54= | Silent (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- GIMAP4 | c.411C>A p.I137= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV55432515; called by muse, mutect2, varscan2
- KIAA0319 | c.543G>A p.E181= | Silent (SNP) | VAF 31/63 reads (49%) | catalogued as rs1261006427; called by muse, mutect2, varscan2
- MZF1 | c.1116G>A p.L372= | Silent (SNP) | VAF 22/67 reads (33%) | called by muse, mutect2, varscan2
- NEFH | c.942G>A p.A314= | Silent (SNP) | VAF 53/213 reads (25%) | catalogued as rs1192848725, COSV60218460; called by muse, mutect2, varscan2
